Somatic mutation profile of tumor specimen TCGA-DJ-A2PV-01A (aliquot TCGA-DJ-A2PV-01A-11D-A19J-08) from TCGA case TCGA-DJ-A2PV, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 53.5 years (19,547 days).
Specimen TCGA-DJ-A2PV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53876817-7718-48cb-99d2-50d81a98d6e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2PV-10A (Blood Derived Normal), aliquot TCGA-DJ-A2PV-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea09caf4-30c2-49b4-9cb8-d247920c29bb

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ANP32A | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.187); catalogued as COSV51189779; called by muse, mutect2, varscan2
- APOB | c.4083T>A p.N1361K | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV51937939, COSV51944923; called by muse, mutect2, varscan2
- CD163 | c.1828T>C p.S610P | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV63135445; called by muse, mutect2
- HEATR1 | c.5632C>T p.R1878* | Nonsense Mutation (SNP) | VAF 43/132 reads (33%) | catalogued as COSV63980437; called by muse, mutect2, varscan2
- RIOK1 | c.877G>A p.V293I | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV53572958; called by muse, mutect2
- IGHV3-35 | c.248T>G p.V83G | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GATC | c.405C>T p.H135= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV57570807, COSV57571312; called by muse, mutect2, varscan2
- RALGAPA2 | c.2100G>A p.R700= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV52504685; called by muse, mutect2, varscan2
